MMRF case MMRF_1634 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f02a53a1-62c5-4e02-bae4-8b9ac0c443fc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 36 years; Vital status: Dead; Days to death: 16 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 37.0 years (13,510 days); ISS stage: II; Days to last known disease status: 16 days; Days to last follow up: 16 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 16 days.

Follow-up (2 entries)
- Days to follow up: -3 days; ECOG performance status: 0.
- Follow-up contact recording only the day: day 16.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Albumin 43 g/L.
- Absolute Neutrophil 5 ×10⁹/L.
- Immunoglobulin M 0.12 g/L.
- Blood Urea Nitrogen 5 mmol/L.
- Serum Free Immunoglobulin Light Chain, Kappa 3.83 mg/dL.
- Hemoglobin 8.43 mmol/L.
- Calcium 2.73 mmol/L.
- Platelets 296 ×10⁹/L.
- Beta 2 Microglobulin 3.57 µg/mL.
- Lactate Dehydrogenase 4.33 µkat/L.
- M Protein 4.1 g/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL.
- Leukocytes 7.1 ×10⁹/L.
- C-Reactive Protein 5.2 mg/dL.
- Total Protein 10.6 g/dL.
- Glucose 5.17 mmol/L.
- Immunoglobulin A 49.2 g/L.
- Immunoglobulin G 3.43 g/L.
- Creatinine 116 µmol/L.

Other clinical attributes
- Day -3: Weight: 70 kg; Height: 172 cm.

Biospecimens (2 samples)
- Sample MMRF_1634_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1634_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
